Surgical pathology report (de-identified scan), TCGA case TCGA-IN-A6RS, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-IN-A6RS-01A (Primary Tumor).

FINAL DIAGNOSIS:

Collection Date:

PART 1: TISSUE AT BASE OF LEFT GASTRIC, EXCISION -
ADIPOSE TISSUE WITH FAT NECROSIS, NEGATIVE FOR TUMOR.

PART 2: TISSUE NEAR RIGHT CRUS, EXCISION -
TWO BENIGN LYMPH NODES (0/2).

PART 3: OMENTUM, EXCISION -
FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

PART 4: LEVEL 7 LYMPH NODE NEAR CARINA, EXCISION -
ONE BENIGN LYMPH NODE (0/1).

PART 5: ESOPHAGUS, ESOPHAGECTOMY -

- A. WELL TO MODERATELY DIFFERENTIATED ADENOCARCINOMA OF THE GASTROESOPHAGEAL JUNCTION, 2.5 CM, PREDOMINANTLY EXOPHYTIC.
- B. THE ADENOCARCINOMA FOCALLY INVADES INTO THE SUPERFICIAL SUBMUCOSA.
- C. BACKGROUND OF HIGH GRADE COLUMNAR DYSPLASIA AND FOCAL INTESTINAL METAPLASIA.
- D. NO ANGIOLYMPHATIC OR PERINEURAL INVASION.
- E. TWENTY-ONE BENIGN PARAESOPHAGEAL LYMPH NODES (0/21).
- F. AJCC PATHOLOGIC STAGE: pT1b N0.
- G. MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR.
- H. INCIDENTAL BENIGN SPINDLE CELL TUMORLET (0.5 CM) IN THE PERIESOPHAGEAL SOFT TISSUE, PENDING FURTHER CHARACTERIZATION TO BE REPORTED AS AN ADDENDUM.

PART 6: DISTAL ESOPHAGEAL LYMPH NODE, EXCISION -
ONE BENIGN LYMPH NODE (0/1).

PART 7: DISTAL ESOPHAGEAL LYMPH NODE #2, EXCISION -
TWO BENIGN LYMPH NODES (0/2).

PART 8: ANASTOMOTIC RINGS, EXCISION -
PORTIONS OF ESOPHAGEAL AND GASTRIC TISSUE, NEGATIVE FOR TUMOR.

PART 9: STOMACH, FINAL GASTRIC MARGIN, EXCISION -
PORTION OF PROXIMAL STOMACH, NEGATIVE FOR TUMOR.

Addendum

Part 5: Morphologic findings and immunostain results (below) demonstrate that the incidental, benign per-esophageal spindle cell neoplasm is best classified as a schwannoma (0.5 cm).

Marker	Result
S100	Positive
Desmin	Negative
KIT	Negative
DOG1	Negative

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY ESOPHAGEAL TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE:	Esophagectomy
TUMOR SITE:	Tumor midpoint centered on esophagogastric junction
TUMOR SIZE:	Greatest dimension: 2.5 cm

----- MICROSCOPIC -----

HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	G2
PATHOLOGIC STAGING (pTNM)	

pT1b
pN0
Number of lymph nodes examined: 27
Number of lymph nodes involved: 0
17 or more regional lymph nodes were identified
pM Not applicable
No prior treatment

PRIOR TREATMENT: MARGINS

Proximal margin uninvolved by invasive carcinoma
Distal margin uninvolved by invasive carcinoma
Circumferential (adventitial) margin uninvolved by invasive carcinoma

ANGIOLYMPHATIC INVASION:

Absent

ADDITIONAL PATHOLOGIC FINDINGS:

Intestinal metaplasia (Barrett's esophagus)
High grade dysplasia

ICD-O-3
Adenocarcinoma NOS 8140/3
Site Gastroesophageal junction
C16.0
QD 8/2/13

Reviewed Initials	BA	Date Reviewed: 8/20/13

Source: NCI Genomic Data Commons file 9d48bf92-cce4-4404-959b-4f462e80c30a (TCGA-IN-A6RS.ACBEB551-8AAB-4D64-8797-5D5DB3B31AD4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).